Clinical report (de-identified scan), EXCEPTIONAL_RESPONDERS case ER-B0GF, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders), specimen ER-B0GF-TTM1-A (Metastatic).

[page 1 of 35]
->

MRN: [REDACTED]
DOB: [REDACTED] Sex: F
Adm: [REDACTED] D/C: [REDACTED] +39

+37

Resulted [REDACTED] Result status: Final
result

SURGICAL PATHOLOGY PROCEDURE (SPECIMEN)

Resulted by: [REDACTED]

Ordering provider: [REDACTED]

Resulting lab: [REDACTED]

Narrative: [REDACTED]

Patient Name: [REDACTED]

Accession #: [REDACTED]

MRN: [REDACTED]

Encounter: [REDACTED]

DOB: [REDACTED]

Gender: F

Client: [REDACTED]

Submitting Physician: [REDACTED]

Procedure Date: [REDACTED] +37

Received: [REDACTED] +37

Accessioned: [REDACTED] +37

Reported: [REDACTED] +38

SURGICAL PATHOLOGY REPORT

FINAL PATHOLOGIC DIAGNOSIS

A. Peritoneum, right upper quadrant, biopsy:

-Benign fibroadipose tissue with focal fat
necrosis

B. Liver, right lobe, biopsy:

-Benign liver with hemangioma/lymphangioma and
probable duct hamartoma

C. Liver, right lobe, biopsy:

-Adenocarcinoma, consistent with metastasis from
pancreas primary
-Associated marked acute inflammation

D. Liver, left lobe, biopsy:

- Benign liver tissue

E. Liver, left lobe, biopsy:

-Benign liver tissue with bile duct hamartoma

Signed Electronically by [REDACTED] +38

Specimen:

A: Peritoneum, right upper quadrant, biopsy

B: Liver, right lobe, biopsy

C: Liver, right lobe, biopsy

D: Liver, left lobe, biopsy

E: Liver, left lobe, biopsy

Clinical Data:

Malignant neoplasm of pancreatic duct.

Frozen Section Diagnosis:

FS#1: Peritoneum, right upper quadrant, biopsy:

-Benign, probably fat necrosis

[page 2 of 35]
+260

Admission

Description: Female DOB

Department

Encounter #

Order

Non Gyn Cytology Request

My Health Connection Notes

Viewed by +309

Written by +262

As we discussed - the lesion in the liver showed spread of cancer from the pancreas to the liver.

Please continue to see your cancer doctors

Best regards,

Non Gyn Cytology Request

Order:

Collected: Status: Final result Visible to patient: Yes

+260

Narrative

Performed by

CYTOLOGY DIAGNOSIS:

Liver, EUS-guided fine needle aspiration:

--Adenocarcinoma with mucinous differentiation (see comment).

Comment: Immunohistochemical stains are performed with appropriate controls. Tumor cells are strongly positive for CK7, focally positive for CK20 and CDX2. Tumor cells are negative for Pax-8 and GATA-3. Given the clinical history of pancreatic cancer (details not available), this immunoprofile would be most consistent with pancreatic primary.

has also reviewed this case and concurs with the diagnosis.

Slides Reviewed: Prep Smears, Cell Block, Immunostains

Clinical History: History of pancreatic cancer, breast cancer and BRCA positive, rule out mets.

Aspiration performed by:

Immediate evaluation by:

Preliminary impression: Pass #1 and #2 (Sufficient) Metastatic

adenocarcinoma and hepatocytes. informed of results on

at

+260

[page 3 of 35]
Date of Procedure: [REDACTED] +260

Source of Specimen:

Liver --FNA, LIVER, 15 mm (EUS GUIDED)

Specimen Prep Description:

2 Passes. 1 pap stained and 1 difquik stained prep smear slides prepared from each pass, received needle rinse in a formalin filled container, 1 cell block prepared (A2).

Number of Cytology Slides: 5.0

Reviewed and Interpreted by:

[REDACTED]

Cytopathology

[REDACTED]

[REDACTED]

The following cases, on this patient, were collected on the same day as this case.

Specimen Collected: [REDACTED] +260

Last Resulted: [REDACTED]

[Order Details](#) [View Encounter](#) [Lab and Collection Details](#) [Routing](#) [Result History](#)

Comments

Order

Ordered by an unspecified provider

Collection Information

[REDACTED]

[page 4 of 35]
Specimen ID [REDACTED]

Resulting Agency: [REDACTED]

View SmartLink Info

Non Gyn Cytology Request (Order [REDACTED]) +260

Result Information

Resulted Date/Time: Final result (Collected [REDACTED]) +260

All Reviewers List

[REDACTED]

Non Gyn Cytology Request

Study Date: [REDACTED] +262

Ordering Provider [REDACTED]

Surgery Report

Lab Printout

Open Hard Copy Result Report (Order [REDACTED])

Order Report

View Order Information

[REDACTED]

[page 5 of 35]
+1661

Office Visit

Description: Female DOB:

Provider:

Progress Notes

Author	Status	Last Editor	Updated
[REDACTED]	Signed	[REDACTED]	[REDACTED]
Created:	[REDACTED]		+1664

Assessment and Plan: +1661

1. **Malignant neoplasm of head of pancreas (HC code)**
2. **Pancreatic cancer metastasized to liver (HC code)**
3. **Diarrhea, unspecified type**

Pancreatic adenocarcinoma: with history of mets to the liver w/ NED since previous treatment (none found in pancreatic head on Whipple)
She is currently on routine surveillance

Last CT Scan review

+1561

CT CAP IMPRESSION: No evidence of local recurrence or distant metastasis.
CA19-9 remain normal. CEA 2.6

Plan to get another labs in 1 months.
CT scan in 4 months.

Fever - Saw ID. They think it is recurrent cholangitis. Has started her on prophylactic antibiotics. Started it yesterday.

Diarrhea/Pancreatic insufficiency. It is better now.

Hx of Breast cancer - BRCA 1 positive. S/p bilateral mastectomy and chemotherapy 30 years ago. Patient has leaky implants. She will consider seeing surgeons again.

Hypothyroidism- followed by Endocrinology

Urinary frequency- still has Nocturia. Will continue to monitor.

Vaginal yeast infection- Intermittent.

Neuropathy of feet -d/t previous chemo, stable overall.

ECOG Score- 1

Subjective:

Patient is [REDACTED] female who presents to [REDACTED]

Interval History:

Still have recurrent fever. It occurs every 3 days. Tmax was 104.

[page 6 of 35]
Also has a bout of diarrhea. Pancreatic enzymes were not working but it got better with her SIBO antibiotics. It is now much better
Still has nocturia.

Oncology History:

Pt states that she began to feel more fatigued and run down beginning in [REDACTED] By [REDACTED] she states that she sought medical care because her skin began to turn more yellow.

Diagnosed at that time with likely pancreatic cancer, CTAB/P at that time showing 3 lesions to liver suspicious for metastasis.

Per chart review, pt was evaluated with laposcopy without additional mets. Since [REDACTED] has undergone 6 cycles of gemcitabine/abraxane from her primary oncologist [REDACTED] at [REDACTED] which she has tolerated well from a symptoms standpoint.

[REDACTED] 6 cycles of gemcitabine and abraxane. She initial has some response but then had progression per CT scan and tumor markers.

[REDACTED] FOLFOX. 2nd cycle had FOLFIRINOX but had an allergic reaction to irinotecan.

SBRT

Present : FOLFOX

CT

1. Slight improvement in burden of pancreatic malignancy. There is decrease in size of hypodense pancreatic head mass measuring approximately 22 x 20 mm, and decrease in main pancreatic ductal dilation. Portal and splenic veins are patent. Mild focal stranding along the SMV is improved since [REDACTED] and may represent tumoral abutment. Hepatic lesions are overall unchanged or smaller in size. There are no new lesions.

2. Filling defect in mid SVC adjacent to the catheter of a left chest port is suspicious for venous thrombosis.

[REDACTED] Classic pancreaticoduodenectomy with liver wedge resection.

CT C/A/P NED

DEXA IMPRESSION:

By WHO criteria, this patient has the diagnosis of osteoporosis.

[REDACTED] CT CAP IMPRESSION:

Stable postoperative changes related to Whipple procedure. No evidence of local recurrence or metastatic disease.

[REDACTED] CT CAP IMPRESSION: No evidence of local recurrence or distant metastasis.

[REDACTED] CT CAP IMPRESSION: No evidence of local recurrence or distant metastasis.

[REDACTED] CT CAP IMPRESSION: No evidence of local recurrence or distant metastasis.

CURRENT MEDICATIONS:

Current Outpatient Prescriptions

Medication	Sig
• BLOOD SUGAR DIAGNOSTIC (FREESTYLE LITE) test strips	1 strip by In Vitro route three times a week.
• CALCIUM CARBONATE (CALCIUM 500 PO)	Take by mouth 2 times daily.
• cefUROXime (CEFTIN) 250 mg tablet	Take 1 tablet by mouth 2 times daily for 10 days for Urinary Tract Infection.
• Cholecalciferol, Vitamin D3, 5,000 unit Cap	Take 5,000 Units by mouth for supplementation.
• CYTOMEL 5 mcg tablet	Take 1 tablet by mouth 2 times daily for hypothyroidism.
• denosumab (PROLIA) 60 mg/mL Syrg syringe injection	Inject 60 mg into the skin every 6 months.
• doxycycline (ADOXA) 100 mg tablet	Take 1 tablet by mouth 2 times daily for SIBO.
• EPINEPHrine (EPIPEN) 0.3 mg/0.3 mL injection	
• estradiol (ESTRING) 2 mg vaginal ring	Place 2 mg vaginally for estrogen replacement therapy. Use as directed 2 mg by physician vaginally every 3 months.

[page 7 of 35]
• FLUoxetine (PROZAC) 20 mg capsule	
• freestyle lancets	1 each by In Vitro route three times a week.
• glucosam-chondroitin-diet cb25 116-100 mg Cap	Take 2 tablets by mouth daily for supplementation.
• levothyroxine (SYNTHROID) 112 mcg tablet	Take 1 tablet by mouth daily for hypothyroidism.
• lip-prot-amylase 20K/63K/84K (ZENPEP) 20,000-63,000- 84,000 unit CpDR per capsule	Take 3 capsules by mouth 3 times daily (with meals) for exocrine pancreatic insufficiency.
• lipase-protease-amylase 20,880-78,300-78,300 unit (VIOKACE) 20,880-78,300- 78,300 unit per tablet	Take 1 tablet by mouth 5 times daily for exocrine pancreatic insufficiency. And with snacks
• losartan-hydrochlorothiazide (HYZAAR) 50-12.5 mg per tablet	Take 1 tablet by mouth daily.
• morphine (MSIR) 15 mg tablet	every 4 hours as needed.
• omeprazole (PRILOSEC) 40 mg capsule	Take 1 capsule by mouth 2 times daily for Heartburn.
• opium tincture 10 mg/mL (morphine) ORAL soln	Take 1 mL by mouth every 4 hours as needed for Diarrhea for Diarrhea.

No current facility-administered medications for this visit.

ALLERGIES: Irinotecan; Oxaliplatin; Bee sting kit; and Levofloxacin

Past Medical History:

Diagnosis	Date
• Arthritis	
• Breast cancer (HC code) BRCA 1 positive, s/p mastectomy and chemotherapy	around -10562
• Cataract	
• Chronic diarrhea	
• Colon polyp	
• Depression	
• Diverticulitis	
• Fractures left arm x 3, left shoulder, right arm, knee cap	
• GERD (gastroesophageal reflux disease)	
• Hypertension	
• Hypothyroidism	
• Liver cancer (HC code)	
• MVA (motor vehicle accident)	around +800
• Osteoporosis on Fosamax x 10 years, then then fracture, then Prolia, now off everything	+1057
• Pancreatic cancer (HC code) with mets to liver s/p Whipple- no chemo due to diarrhea (BRCA gene positive)	
• Papillary thyroid carcinoma (HC code) 0.9 cm Hurthle cell, s/p NTT and RAI Rx 100 mCi I-131	

Past Surgical History:

Procedure	Laterality	Date
• APPENDECTOMY		
• Breast reconstructive surgery		around -10562
• BREAST SURGERY		
• COLONOSCOPY		

[page 8 of 35]
• ELBOW SURGERY	Right	around +400
• ENDOSCOPY		
• EYE SURGERY		
• FOOT FRACTURE SURGERY	Right	around +400
• FRACTURE SURGERY	Left	around +400
Collarbone		
• HYSTERECTOMY, TOTAL ABDOMINAL		around -11658
• IR PORT REMOVAL		+1464
IR PORT REMOVAL [REDACTED] AMC IR		
• LIVER BIOPSY		
• MASTECTOMY	Bilateral	around +400
• SHOULDER SURGERY		
humerus fracture		
• SPINE SURGERY		
• THYROIDECTOMY		around -2892
• tibial plateau fracture	Left	around +400
x 3		
• TONSILLECTOMY		
• UPPER GASTROINTESTINAL		
ENDOSCOPY		
• Whipple	N/A	+847

Family History

Problem	Relation	Age of Onset
• Breast cancer	Mother	
breast cancer - BRCA		
• Colorectal Cancer	Maternal Grandmother	
• Bleeding prob	Neg Hx	
• Clotting disorder	Neg Hx	
• Early CAD	Neg Hx	
• Anesth problems	Neg Hx	
• Thyroid disease	Neg Hx	

Social History**Social History**

- Marital status:
- Spouse name:
- Number of children:
- Years of education:

Occupational History

- [REDACTED]

Social History Main Topics

- Smoking status: Never Smoker
- Smokeless tobacco: Never Used
- Alcohol use: 4.2 oz/week
- 7 Glasses of wine per week
- Comment: daily
- Drug use: No
- Sexual activity: Not Currently

Other Topics

- Not on file

Concern

Social History Narrative

[page 9 of 35]
- No narrative on file

Review of Systems

Constitutional: Negative.
HENT: Negative.
Eyes: Negative.
Respiratory: Negative.
Cardiovascular: Negative.
Gastrointestinal: Positive for diarrhea.
Genitourinary: Negative.
Musculoskeletal: Negative.
Skin: Negative.
Neurological: Positive for numbness.
Psychiatric/Behavioral: Negative.

Objective:

Vital Signs:

Visit Vitals

BP	132/63
Pulse	74
Temp	36.7 °C (98 °F) (Temporal Artery)
Resp	16
Wt	(!) 39.8 kg (87 lb 12.8 oz)
SpO2	91%
BMI	14.84 kg/m ²

Physical Exam

Constitutional: She is oriented to person, place, and time. No distress.
HENT:
Mouth/Throat: No oropharyngeal exudate.
Eyes: No scleral icterus.
Neck: Neck supple. No thyromegaly present.
Cardiovascular: Normal rate, regular rhythm and normal heart sounds. Exam reveals no friction rub.
No murmur heard.
Pulmonary/Chest: Effort normal and breath sounds normal. No respiratory distress.
Abdominal: Soft. Bowel sounds are normal. She exhibits no distension.
Musculoskeletal: She exhibits no edema.
Neurological: She is alert and oriented to person, place, and time. No cranial nerve deficit.
Skin: Skin is warm and dry. No rash noted.
Psychiatric: She has a normal mood and affect. Her behavior is normal.
Vitals reviewed.

Procedures

None

DATA:

Laboratory results reviewed.

Results for orders placed or performed in visit on [REDACTED] +1661

Comprehensive Metabolic Panel

Result	Value	Ref Range
Sodium Serum/Plasma	125 (L)	133 - 145 mmol/L
Potassium Serum/Plasma	3.8	3.5 - 5.1 mmol/L
Chloride Serum/Plasma	90 (L)	98 - 108 mmol/L
Carbon Dioxide	25	21 - 31 mmol/L
Anion Gap	10	4 - 16 mmol/L

[page 10 of 35]
Glucose Serum/Plasma	110	70 - 199 mg/dL
Blood Urea Nitrogen	9	7 - 25 mg/dL
Creatinine Serum/Plasma	0.59 (L)	0.60 - 1.20 mg/dL
eGFR if Non-African American	>60	>=60 mL/min/1.73 "square meters"
eGFR if African American	>60	>=60 mL/min/1.73 "square meters"
Calcium Serum/Plasma	8.5 (L)	8.6 - 10.3 mg/dL
Bilirubin Total	0.6	0.1 - 1.3 mg/dL
Alkaline Phosphatase Total	43	39 - 117 U/L
Alanine Aminotransferase	15	7 - 52 U/L
Aspartate Aminotransferase	28	12 - 39 U/L
Protein Total Serum/Plasma	6.4	6.4 - 8.9 g/dL
Albumin	4.1	3.5 - 5.7 g/dL
Carcinoembryonic Antigen (CEA)		
Result	Value	Ref Range
Carcinoembryonic Antigen DXI	2.5	0.0 - 3.0 ng/mL
CBC with Auto Differential		
Result	Value	Ref Range
White Blood Cell Count	6.4	4.0 - 11.1 10 ⁹ /L
Red Blood Cell Count	3.89 (L)	4.18 - 5.64 10 ¹² /L
Hemoglobin	11.1 (L)	12.1 - 16.3 g/dL
Hematocrit	32.7 (L)	35.7 - 46.7 %
Mean Corpuscular Volume	84.1	80.0 - 100.0 fL
Mean Corpuscular Hemoglobin	28.5	27.5 - 35.1 pg
Mean Corpuscular Hemoglobin Concentration	33.9	32.0 - 36.0 g/dL
Platelet Count	237	150 - 400 10 ⁹ /L
Red Cell Distribution Width CV	16.3 (H)	11.7 - 14.2 %
Segmented Neutrophil Percent	64.9	%
Lymphocyte Percent	21.2	%
Monocytes Percent	11.9	%
Eosinophils Percent	0.8	%
Basophils Percent	0.9	%
Immature Granulocytes Percent	0.3	%
Neutrophils Absolute	4.1	1.8 - 6.6 10 ⁹ /L
Lymphocyte Absolute	1.4	1.0 - 4.8 10 ⁹ /L
Monocytes Absolute	0.8	0.2 - 0.9 10 ⁹ /L
Eosinophils Absolute	0.1	0.0 - 0.4 10 ⁹ /L
Basophils Absolute	0.1	0.0 - 0.2 10 ⁹ /L
Immature Granulocytes Absolute	0.0	0.0 - 0.05 10 ⁹ /L
NRBC Percent	0.0	0 %
NRBC Absolute	0.00	0 10 ⁹ /L
Cancer Antigen 19-9 (GI)		
Result	Value	Ref Range
Cancer Antigen 199 DXI	25.0	0.0 - 35.0 U/mL

TIME/COUNSELING:

I personally spent a total of 30 minutes. Of that 25 minutes was counseling/coordination of patient's care. See my note above for details.

Electronically signed by [REDACTED]

+1664

[page 11 of 35]
+1661

Office Visit on [redacted] Note shared with patient

Communications

Chart Routed to Gi Phase1 [redacted]

Letter sent to [redacted]

Revision History Audit Trail

	Date/Time	User	Provider Type	Action
+1664	[redacted]		Physician	Sign
+1664			Physician	Sign at close encounter
+1664			Physician	Sign at close encounter

[page 12 of 35]
+2308

Encounter

ent:

Surgical Pathology Request

Order:

Status: Final result Visible to patient: Yes Next appt: None

Narrative

Performed by:

FINAL DIAGNOSIS**SYNOPTIC REPORT FOR THE PANCREATIC HEAD TUMOR:**

Comment: A distinct mass is not appreciated on gross examination. No tumor cells are identified in the entirely submitted pancreas and peripancreatic tissue. There are changes consistent with treatment effect, including subtotal atrophy of the pancreatic exocrine tissue, extensive dense fibrosis and elastosis, numerous hemosiderin laden macrophages, giant cell reaction, and radiation vasculopathy. Rare foci of low-grade pancreatic intraepithelial neoplasia remain.

Tumor Site: By report, pancreatic head (periampullary)

Tumor Size: Cannot be determined (no residual tumor after neoadjuvant therapy)

Histologic Type: Cannot be determined (by report, pancreatic mucinous adenocarcinoma)

Histologic Grade: GX (cannot be assessed)

Microscopic Tumor Extension: No evidence of primary tumor

Margins: Margins uninvolved by invasive carcinoma

Treatment Effect: Present; no viable cancer cells (complete response; score 0)

Lymph-Vascular Invasion: Not identified

Perineural Invasion: Not identified

Pathologic Staging: ypT0 N0 (stage 0)

Number of Lymph Nodes Examined: 20 (17 in part A + 2 in part B +1 in part C)

Number of Lymph Nodes Involved by Carcinoma: 0

A) Liver (biopsy):

- Benign solitary bile duct cyst.
- No carcinoma.

[page 13 of 35]
B) Whipple (pancreaticoduodenectomy):

- No residual tumor after neoadjuvant therapy (see synoptic report above).

C) Lymph node, peripancreatic (excision):

- Two lymph nodes, negative for malignancy (0/2).

D) Gallbladder (cholecystectomy):

- Chronic acalculous cholecystitis
- One lymph node, negative for malignancy (0/1).

CLINICAL HISTORY

+37

Patient with pancreatic adenocarcinoma diagnosed in [REDACTED] who presented with a liver lesion and biopsy confirmed cancer. The patient is now status post chemotherapy with significant radiographic response. The patient is also known to be BRCA-1 gene mutated.

GROSS DESCRIPTION

Two Specimens are received fresh of intraoperative consultation, labeled [REDACTED]

A) Designated "liver biopsy," is a single pink-tan fragment of liver parenchyma which measures 0.4 x 0.3 x 0.2 cm. The entire specimen is frozen for intraoperative consultation and the residual tissue is submitted as (FSA1).

B) Designated "Whipple," is a segment of stomach and duodenum (20.5 x 3.5 x 2.0 cm) and pancreas (3.5 x 3.5 x 1.6 cm). The entire external surface is inked black. The bowel is opened revealing unremarkable gastric and duodenal mucosa. The pancreatic neck margin, the bile duct margin, and the uncinate margin are dissected off. The bile duct is opened exposing the ampulla. There is no ampullary mass. The bile duct appears smooth and is without masses or lesions. The pancreatic head is serially sectioned to reveal a diffusely white-tan and fibrotic cut surface with no normal appearing pancreatic parenchyma. No discrete masses are identified. Three dumbbell shaped metal fragments (0.3 x 0.1 x 0.1 cm, each) are embedded within the periampullary pancreas. A minimal amount of unremarkable peripancreatic fat is present with no grossly identifiable lymph nodes. The entire pancreas and parapancreatic fat is submitted. The specimen is submitted as follows:

(FSB1) Pancreatic neck margin, en face (frozen section remnant)

(FSB2) Bile duct margin, en face (frozen section remnant)

(FSB3) Uncinate margin, en face (frozen section remnant)

(B4) Representative section of periampullary pancreatic parenchyma

[page 14 of 35]
(B5-B6) Pancreatic head parenchyma near neck margin
(B7-B9) Pancreatic uncinate and peripancreatic fat
(B10-B11) Posterior superior pancreas and peripancreatic fat
(B12-B14) Periapulla, left of bile duct (area with metal dumbbell fragments)
(B15-B19) Periapulla, right of bile duct
(B18) Stomach margin
(B19) Duodenal margin

Two Specimens are received in formalin, labeled [REDACTED]

C) Designated "peripancreatic lymph node," are two pink-tan soft tissue fragments with aggregate dimensions of 2.2 x 1.1 x 0.6 cm. Both fragments are palpated and no obvious lymph nodes are identified. Each fragment is bisected and entirely submitted as (C1-C2).

D) Designated "gallbladder," is an intact gallbladder measuring 9.0 x 3.2 x 1.6 cm. The serosal surface is white-tan and smooth and without lesions. The lumen of the gallbladder is opened expressing approximately 20cc of dark green bile. The mucosa is smooth and bile-stained and without lesions. The wall thickness is 0.3 cm. There is a cystic duct lymph node present. Representative sections of the specimen including the cystic duct margin, cystic duct lymph node are submitted as (D1). [REDACTED]

INTRAOPERATIVE DIAGNOSIS

FSA1: Liver biopsy: Benign liver with simple cyst; negative for carcinoma

FSB1: Pancreatic neck margin: Atypical epithelial cells near vessel, of unknown significance

FSB2: Bile duct margin: Negative

FSB3: Uncinate margin: No definitive carcinoma at uncinate margin, limited by cautery artifact

Intra-Operative Diagnosis Reviewed and Interpreted By:

[REDACTED]

[REDACTED]

[REDACTED]

[page 15 of 35]
Final Diagnosis Reviewed and Interpreted by:

ELECTRONICALLY SIGNED

Date:

+851

Comments

Ordered by an unspecified provider

Provider Information

Ordering User

Ordering Provider

Authorizing Provider

Attending Provider(s)

Admitting Provider

PCP

Specimen Information

Specimen ID

Collected: +847

Received: +847

Lab Information

[page 16 of 35]
->

MRN
DOB
Adm:

Sex: F

+0

Resulted: +0 Result status: Final result

CT Abdomen And Pelvis W Contras

Ordering provider:

Resulting lab:

Narrative:

ruq abd pain jaundice

Performed:

EXAM: CT ABD/PELVIS W CONTRAST

+0

HISTORY: ruq abd pain jaundice

COMPARISON: None

FINDINGS: Helical axial images were obtained from the abdomen through the pelvis following intravenous administration of 75 ml of Omni 350. The patient ingested positive oral contrast. Sagittal coronal reformations were performed.

There is a 3.3 x 2.4 cm heterogeneous mass in the head of the pancreas causing intra hepatic biliary, extrahepatic biliary, and pancreatic ductal dilatation. Additionally the gallbladder is distended and there is pericholecystic fluid. In the inferior posterior right lobe of the liver is seen on image 43 series 3 there is a 4.5 mm hypodense lesion that is too small to accurately measure in Hounsfield units. The spleen, adrenal glands and right kidney appear normal. There is a 1.2 cm simple-appearing left renal cortical cyst. The abdominal aorta is normal in caliber and there are no enlarged retroperitoneal lymph nodes. The bowel as imaged appears unremarkable. There is no ascites. There are no osseous sclerotic or lytic bone lesions. The imaged portions of lung bases are clear.

IMPRESSION:

1. THERE IS A 3.3 X 2.4 CM HETEROGENEOUS MASS WORRISOME FOR MALIGNANCY IN THE HEAD OF THE PANCREAS CAUSING BILIARY DUCTAL AND PANCREATIC DUCTAL DILATATION.
2. THERE IS A 4.5 MM HYPODENSE RIGHT LOBE LIVER LESION THAT IS TOO SMALL TO ACTUALLY MEASURE IN HOUNSFIELD UNITS AND IS NONSPECIFIC IN APPEARANCE.

FINDINGS WERE DISCUSSED WITH AT HOURS.

+4

Resulted: Result status: Edited Result - FINAL

CT Chest W Contrast

Ordering provider:

Resulting lab:

Narrative:

new diagnosis pancreas cancer, r/o mets

Performed:

Addendum Begins

Corrected report:

[page 17 of 35]
->

MRN: [REDACTED]
DOB: [REDACTED], Sex: F
Adm: [REDACTED] D/C: [REDACTED]

+0

+0

FINDINGS:

A focal area of pleural thickening along the course of the major fissure on the left is again identified, not significantly changed from [REDACTED]. This measures approximately 7-8 mm in left-right dimension. -2365

+1

Addendum Ends

EXAM: CT CHEST W/ CONTRAST, [REDACTED]

INDICATIONS: New diagnosis pancreatic carcinoma..

FINDINGS: Left chest:

Helical CT scan is performed through the chest during the IV injection of 75 ml Omnipaque 350.

Scans of the mediastinum demonstrate a small amount of calcification within the right subclavian artery and aortic arch. An aortic origin of the left vertebral artery is present. No mediastinal adenopathy is identified. There is one mediastinal lymph node in the pretracheal space measuring approximately 13 mm in diameter.

Mammary implants are present bilaterally.

No axillary adenopathy identified.

No pleural fluid is identified.

There is no evidence of pericardial effusion.

No pulmonary masses are identified. There is no evidence of pulmonary metastasis. A focal area of pleural thickening along the course of the major fissure on the left is again identified not significantly changed from [REDACTED]. This measures approximately seven - 8 mm and left-right dimension. -2365

No osseous lesions are detected.

There are linear densities at the lung bases suggesting areas of scarring or atelectasis. Some subpleural atelectasis is present in both posterior costophrenic sulci.

[page 18 of 35]
->

MRN: [REDACTED]
DOB: [REDACTED] Sex: F
Adm: [REDACTED] D/C: [REDACTED]

+0

+0

IMPRESSION:

1. NO CT EVIDENCE OF METASTATIC DISEASE TO THE THORAX

+16

Resulted: [REDACTED] Result status: Edited
Result - FINAL

CT Abdomen Wo/W Contrast [REDACTED]

Ordering provider: [REDACTED]

Resulting lab: [REDACTED]

Narrative:

new diagnosis pancreas cancer (hx breast, thyroid ca in past)

Performed: [REDACTED]

+1

Addendum Begins

The standard portal venous phase of the pancreatic mass protocol CT was not performed on this exam as a portal venous phase CT abdomen/pelvis was done the previous day.

+1

Addendum Ends

EXAM: CT ABDOMEN WWO CONTRAST [REDACTED]

[page 19 of 35]
->

MRN: [REDACTED]
DOB: [REDACTED] Sex: F
Adm: [REDACTED] D/C: [REDACTED]

INDICATIONS: New diagnosis pancreatic carcinoma. History of breast +0 +0
and thyroid carcinoma. Right upper quadrant pain. Previous
appendectomy hysterectomy and mastectomy.

FINDINGS: Helical CT scanning is performed through the abdomen
before and after the intravenous administration of contrast agent, 75
mL of Omnipaque 350. Scans are performed through the liver during
the arterial phase of contrast enhancement. Comparison is made to a
prior study done approximately 24 hours earlier.

A percutaneous biliary stent is in place with its distal tip in the
duodenum. It traverses the left lobe of the liver. Intrahepatic
bile duct dilatation which was evident on the prior study on
[REDACTED] appears to have diminished.

+0

A thick walled gallbladder containing contrast and bile is
demonstrated.

There is a probable mass in the liver demonstrated on image number 99
of series 5 exhibiting rim enhancement in the low density center. On
the previous portal venous exam, it is likely visible on image number
17 of series 3, [REDACTED] A second low density mass in the most
inferior portion of the liver is identified low in density on image
132. Both of these masses measure approximately 8-9 mm in diameter.

+0

No splenic abnormalities are detected. The spleen is not enlarged.

No adrenal masses are detected.

There is dilatation of the pancreatic duct throughout most of the
pancreas. A low density mass is present in the head of the pancreas
extending into the uncinate process and consistent with pancreatic
carcinoma.

This mass measures approximately 2.7 cm in left-right dimension.

I do not identify encasement of the superior mesenteric artery or
celiac axis.

No definite peripancreatic lymphadenopathy identified.

Previous exam demonstrates a well-defined low-density mass in the
lateral cortex of the left kidney compatible with a cyst. There is
no evidence of hydronephrosis.

Calcification of the aorta is present without aneurysm.

No dilatation of bowel identified.

There is a compression deformity of the superior endplate of L1. No
underlying pathologic focus is identified within this vertebral body.]

IMPRESSION:

1. PERCUTANEOUS BILIARY DUCTAL DRAINAGE HAS BEEN PERFORMED WITH A
DECREASE IN THE SIZE OF THE INTRAHEPATIC BILE DUCTS COMPARED TO PRIOR
PREPROCEDURE CT [REDACTED] +0

[page 20 of 35]
→

MRN: [REDACTED]
DOB: [REDACTED] Sex: F
Adm: [REDACTED] D/C: [REDACTED]

2. TWO SMALL LIVER MASSES INDIVIDUALLY 8-9 MM IN DIAMETER. +0
3. 2.7 CM MASS IN THE HEAD OF THE PANCREAS COMPATIBLE WITH AN ADENOCARCINOMA.
4. THICK-WALLED GALLBLADDER.
5. LOW-DENSITY MASS, LEFT KIDNEY MOST CONSISTENT WITH A BENIGN CYST.]

XR ERCP

Ordering provider: [REDACTED]
Resulting lab: [REDACTED]
Narrative:
possible stent

Performed

Resulted: [REDACTED] Result status: Final result

EXAM: FLUOROSCOPIC IMAGES FROM AN ERCP PERFORMED [REDACTED] AT [REDACTED]

HISTORY: Pancreatic mass resulting in biliary obstruction.

COMPARISON: CT scan of the abdomen with without contrast performed [REDACTED]

TECHNIQUE: Two fluoroscopic images from an ERCP procedure were submitted for interpretation. A total of 2.8 minutes of fluoroscopy time was administered without the presence of a radiologist.

FINDINGS: The first image demonstrates cannulation of the common bile duct with contrast demonstrating marked extrinsic narrowing the level of the pancreatic head which is traversed by a guide wire. The second image demonstrates interval placement of a metal biliary stent across the region of narrowing.

IMPRESSION:

EXTRINSIC COMPRESSION OF THE COMMON BILE DUCT FROM THE PATIENTS PANCREATIC MASS WITH SUBSEQUENT PLACEMENT OF A METAL BILIARY STENT.

CT Chest Abdomen And Pelvis W Contrast

Resulted by: [REDACTED]
Resulting lab: [REDACTED]
Narrative:

Performed

Resulted: [REDACTED] Result status: Final result

[page 21 of 35]
->

MRN

DOB

Adm

Sex: F

D/C:

EXAM: Chest, abdomen and pelvis CT scan with contrast

+0

+0

HISTORY: Pancreatic, breast and thyroid cancer

+1

+0

COMPARE: [REDACTED] and [REDACTED]

FINDINGS: Axial, sagittal and coronal images were obtained following the intravenous injection of 100 ml of Omnipaque 350, and oral contrast.

Degenerative abnormalities and L1 compression fracture again seen in the spine.

In the chest, there are several borderline prominent paratracheal nodes, which are stable. Heart size remains normal. There is no significant pericardial effusion. Atherosclerosis is seen in the aorta. There are no suspicious pulmonary nodules or masses, or significant pleural based disease.

In the abdomen, a stent has been placed in the common bile duct, and there is air in the nondependent biliary system. There is prominent, chronic-appearing dilatation of the pancreatic duct, which is unchanged. The previously demonstrated percutaneous biliary drainage tube has been replaced by the stent. Soft tissues surrounding the stent could represent, at least in part, a mass in the head of the pancreas. It is difficult to differentiate bowel from pancreatic tissue on these images, with suboptimal opacification of the duodenal sweep. Also noted is a mildly prominent pattern of contrast enhancement the distal small bowel. This may simply represent bolus timing of the contrast injection. It appears more homogeneous than what would be seen with disseminated malignant involvement of the bowel surface.

Also noted in the abdomen, there are three hepatic lesions with the largest lesion seen best on images 41 and 40 of series #5, which appears to be new and could represent metastatic disease. This lesion measures approximate 9.5 mm in maximal diameter, in the axial plane. The other two lesions are not significantly changed and are of indeterminate etiology and could represent a benign entity. These are located in the lower tip of the right lobe and in the upper medial segment left lobe, on images 24 and 57 of series #5

In the retroperitoneum, benign-appearing left renal cyst is seen. Calcified plaque is present in the aorta the adrenal glands are unremarkable.

In the pelvis, the bladder is urine distended. A pessary is present in the upper vagina. No pelvic masses or fluid collections are seen.

IMPRESSION:

1. STABLE APPEARANCE TO STRUCTURES IN THE CHEST, WITH BORDERLINE PARATRACHEAL ADENOPATHY BUT NO SIGNIFICANT INTERVAL CHANGES.
2. IN THE ABDOMEN, AN INDWELLING BILIARY STENT HAS BEEN PLACED, WITH ROUTINE AIR IN THE NONDEPENDENT INTRAHEPATIC BILIARY SYSTEM, AND CHRONIC DILATATION OF THE PANCREATIC DUCT, SHOWING NO CHANGE
3. ALSO NOTED IN THE ABDOMEN, THERE ARE THREE SMALL HYPODENSE LESIONS IN THE LIVER, ONE LESION APPEARING TO BE NEW AND POSSIBLY REPRESENTING METASTATIC DISEASE.
4. IN THE PELVIS, NO METASTATIC DISEASE IS IDENTIFIED

+148

Resulted

Result status: Edited

Result - FINAL

CT Chest Abdomen And Pelvis W Contrast

Resulted by:

Performed

Resulting lab

+148

Addenda signed by on

ADDENDUM

The ill-defined low density the surrounding the biliary stent involving the pancreatic head and uncinate process is concerning for the underlying

[page 22 of 35]
MRN: [REDACTED]

DOB: [REDACTED]

Adm: [REDACTED]

Sex: F

D/C: [REDACTED]

pancreatic neoplasm, especially given the ongoing chronic pancreatic duct dilatation.

+0

+0

Narrative:

EXAM: CT of the chest, abdomen, and pelvis (with contrast) [REDACTED]

+184

HISTORY: Malignant neoplasm of the pancreas. Study done to evaluate response to chemotherapy. History of breast and thyroid cancer, as well. Fifth series of treatment for pancreatic cancer. History of bilateral mastectomies, bile duct stent, and hysterectomy.

TECHNIQUE: Spiral CT imaging is performed through the chest with 3 mm thickness and reconstruction intervals utilizing 100 ml of Omnipaque 350 intravenously. Sagittal and coronal reconstructions are obtained. Spiral CT is then performed through the abdomen and pelvis utilizing intravenous contrast and enteric contrast. Sagittal and coronal reconstructions are performed.

FINDINGS:

+123

CT of the chest: Comparison is made with prior chest CT dated [REDACTED]. Currently, the true and false cords appear symmetric. The thyroid lobes are symmetric in size. There is a separate origin of the left vertebral artery off the arch of the aorta representing anatomic variation. A left paratracheal pair of lymph nodes is identified and appears smaller than on the prior study. These nodes measure 8 mm in size respectively. They were larger on the prior study, measuring as much as 15 mm. There is a prominent lymph node in the precarinal location measuring 11.2 mm. This node was also PROP larger on the prior study. No new areas of adenopathy are appreciated. Heart size is normal. No pleural effusions are appreciated.

On lung windows, I see no obvious pulmonary nodules, masses, or infiltrates. There is slight posterior compressive atelectasis in the lower lobes. Bilateral implants are present.

On bone windows, no bony destructive changes are appreciated. There is a moderate compression deformity of L1 which appears unchanged from prior study.

CT of the abdomen and pelvis: Again, bilateral breast implants are present. The liver shows air, primarily in the left hepatic lobe ducts but to a lesser extent in the anterior right hepatic lobe ducts, as well. The areas of hypodensity previously seen in the liver appear smaller than on the prior study. There is still a vague hypodense area in the right hepatic lobe and several hypoechoic areas are seen more inferiorly in the right hepatic lobe. The lesion in the posterior tip of the right hepatic lobe measures 5 mm on today's study. Previously, that lesion measured almost 6 mm.

There is no ascites appreciated. Small amount of pericardial fluid is present.

The right kidney shows no mass or obstruction. Left kidney shows a 15.5 mm cyst. The biliary stent is present and are areas of ill-defined low density in the pancreatic head and uncinata process. There is continued dilatation of the pancreatic duct without significant change.

The spleen appears normal. There is no peripancreatic edema.

The right adrenal gland appears normal. The right kidney shows no mass or obstruction. The left adrenal gland appears grossly normal. There is a cyst in the left posterolateral kidney measuring almost 16 mm.

There is no gross retroperitoneal adenopathy visualized.

In the pelvis, there is no free fluid in the cul-de-sac. Uterus is surgically absent. There is considerable stool in the rectum. There is no gross distension of large or small bowel. Colonic diverticuli are visualized.

On the reconstructed images, the compression deformity of L1 is again appreciated. There is a vacuum

[page 23 of 35]
->

MRN: [REDACTED]
DOB: [REDACTED] Sex: F
Adm: [REDACTED] O/C: [REDACTED]

degenerative change in the L4-L5 level.

+0

+0

Iliac vessels appear symmetric in size. The abdominal aorta is normal in size.

IMPRESSION:

CHEST:

1. THERE HAS BEEN INTERVAL DECREASE IN SIZE OF PRECARINAL AND PARATRACHEAL LYMPH NODES SINCE THE PRIOR STUDY OF [REDACTED] SUGGESTING THAT THESE MAY BE METASTATIC NODES WHICH ARE IMPROVING.
2. NO PULMONARY NODULES OR INFILTRATES ARE APPRECIATED. NO PLEURAL EFFUSIONS.
3. NO NEW AREAS OF MEDIASTINAL OR HILAR ADENOPATHY ARE APPRECIATED.
4. BILATERAL BREAST IMPLANTS.
5. NO BONY DESTRUCTIVE LESIONS ARE APPRECIATED.
6. INFUSION PORT CATHETER PRESENT.
7. VERY SMALL PERICARDIAL EFFUSION WITH BORDERLINE HEART SIZE, EXAGGERATED BY THE DIMINISHED INSPIRATION.

CT OF THE ABDOMEN AND PELVIS:

1. THE THREE HYPODENSE LESIONS SEEN IN THE LIVER ON THE PRIOR STUDY APPEAR SMALLER SUGGESTING IMPROVING METASTATIC DISEASE.
2. ILL-DEFINED LOW DENSITY IN THE PANCREATIC HEAD AND UNCINATE PROCESS WITH A BILIARY STENT PRESENT, LIKELY ACCOUNTING FOR THE PNEUMOBILIA. THERE CONTINUES TO BE SIGNIFICANT DILATATION OF THE PANCREATIC DUCT WITHOUT SIGNIFICANT CHANGE. THIS DUCT MEASURES AS MUCH AS 10.4 MM IN DIAMETER.
3. POSTERIOR LEFT RENAL CYST MEASURING 15.5 CM.
4. NO ASCITES APPRECIATED. NO GROSS DISTENSION OF LARGE OR SMALL BOWEL.
5. DEGENERATIVE CHANGES IN THE LUMBAR SPINE. STABLE COMPRESSION DEFORMITY OF L1.

+239

Resulted: [REDACTED] Result status: Final result

CT Chest Abdomen And Pelvis W Contrast [REDACTED]

Ordering provider: [REDACTED]

Resulted by: [REDACTED]

Performed [REDACTED]

Resulting lab [REDACTED]

Narrative: +239

EXAM: CT CHEST ABDOMEN AND PELVIS W CONTRAST

COMPARISON

+184

INDICATION: HX PANCREAS CA EVAL RESPONSE TO TREATMENT. 100ml omni 350, 20ml saline, volumetric, power port. Per patient- pancreatic, thyroid, breast CA. Evaluating chemo response to pancreatic CA. No complaints today. surg- bilat mastectomy, GB stent, hysterectomy. [REDACTED]

TIME OF EXAM

TECHNIQUE: CT scan through the chest, abdomen and pelvis following 100 ml intravenous Omnipaque 350. Examination includes biphasic imaging technique through the abdomen and pelvis. Axial, coronal, and sagittal reformats were obtained.

FINDINGS:

CT chest:

There is mild cardiomegaly. No pericardial effusion. Bilateral breast implants with probable chronic capsular rupture bilaterally which appears similar to previous examination although there are

[page 24 of 35]
->

MRN:

DOB:

Sex: F

Adm:

D/C:

+0

+0

foci of gas within both breast implants which is new since the previous examination. There are atherosclerotic changes of the aorta. There is some respiratory motion artifact during the examination and small areas of peripheral intralobular fibrosis in the upper lobes and lung bases without change. No pulmonary parenchymal metastases are detected. Stable 8 mm right 6 mm nonspecific lymph node between the left vertebral artery and left subclavian artery. Stable appearing indwelling central venous catheter. Stable shotty nonspecific mediastinal lymph nodes without change. No new adenopathy detected. No signs of skeletal metastatic disease. Stable appearing compression fracture of the superior L1 endplate, no change. Stable degenerative changes of the spine.

CT abdomen:

Slight decreased attenuation adjacent to the falciform ligament in the left hepatic lobe likely the hepatic pseudolesion without change. Stable small low density nodule or cyst in the lower posterior right hepatic lobe measuring approximately 5 mm without change. There is a small approximate 8 mm vague hypodensity in the lateral aspect of the right hepatic lobe on axial images 32 of sequence #16, without significant change. There is a tiny 4 mm cyst or low density nodule in the posterior upper right hepatic lobe axial image number 21 without change. There is a persistent biliary stent with pneumobilia and some gas within the gallbladder lumen but without significant change. The spleen, adrenal glands, and kidneys are notable only for a stable left renal cyst. There is calcific aorto-iliac atherosclerosis. There is heterogeneous pancreatic head tumor measuring 4 cm maximum diameter on image 52 of sequence #13 in the AP dimension, slightly increased in size compared to the previous examination where the mass measured 3.6 cm AP diameter on image 56 of sequence #7. Persistent diffuse pancreatic duct dilatation appears stable. There is fluid distension of small bowel loops throughout the abdomen and pelvis the.

CT pelvis:

Urinary bladder is unremarkable. A pessary is noted. Uterus is absent. No discrete adnexal abnormality detected. No definite pathologic pelvic adenopathy. No free pelvic fluid. Stable the sacral Tarlov cyst.

IMPRESSION:

1. THE PANCREATIC HEAD MASS APPEARS SLIGHTLY INCREASED IN SIZE COMPARED TO THE PREVIOUS EXAMINATION. PERSISTENT DIFFUSE PANCREATIC DUCT DILATATION APPEARS STABLE.
2. SMALL SUBCENTIMETER HEPATIC HYPODENSITIES APPEARS STABLE.
3. STABLE-APPEARING BILIARY STENT AND PNEUMOBILIA.
4. NEW BUBBLES OF GAS WITHIN BILATERAL BREAST IMPLANTS COMPARED TO [REDACTED] UNCLEAR ETIOLOGY, QUERY POSSIBLE INFECTION WITH GAS-FORMING ORGANISM. CORRELATION NEEDED CLINICALLY.
5. FLUID DISTENSION WITHIN LOOPS OF SMALL BOWEL BUT WITHOUT EVIDENCE FOR OBSTRUCTION.
6. NO NEW PATHOLOGIC ADENOPATHY DETECTED.
7. STABLE APPEARING L1 COMPRESSION FRACTURE, NO CHANGE.
8. OTHER CHRONIC AND STABLE APPEARING FINDINGS FURTHER DESCRIBED ABOVE.

+184

THE ABOVE RESULTS WERE TELEPHONED TO [REDACTED] AT THE TIME OF INTERPRETATION.

[page 25 of 35]
RADIOLOGY REPORT**Patient Information**

Age/Sex: [REDACTED] Female

Birth Date: [REDACTED]

Visit #: [REDACTED]

HART: [REDACTED]

Signs & Symptoms: Hx of pancreatic cancer

History: Malignant neoplasm of pancreas (HC code)

Order Information

Exam(s): CT CHEST/ABD/PELV W CONTRAST [REDACTED]

Accession #: [REDACTED]

Exam Date: [REDACTED]

+344

Ord Provide: [REDACTED]

Final

CT OF THE CHEST, ABDOMEN, AND PELVIS WITH IV CONTRAST

DATE: [REDACTED] +344

INDICATION: History of pancreatic cancer. Response to chemotherapy and radiation

TECHNIQUE: Transverse axial images of the chest, abdomen, and pelvis were obtained from the apex of the lungs to the proximal thigh after the uneventful administration of intravenous contrast material, Isovue-370, 66 mL. Coronal and sagittal reformatted images were submitted and evaluated.

COMPARISON: Outside CT chest abdomen pelvis [REDACTED] and radiation oncology CT [REDACTED]

FINDINGS:

+241

+263

CHEST:

Thyroid: Diminutive/partially imaged. No focal lesions in visualized portions.

Chest wall and breasts: Bilateral breast implants with irregular contour and internal structure, unchanged from prior. Left chest port with central venous catheter in the superior cavoatrial junction. Mild prominence of right axillary lymph nodes, not enlarged and unchanged from. There is no significant supraclavicular or axillary lymphadenopathy.

Thoracic aorta and pulmonary arteries: Normal caliber aorta and main pulmonary artery with no pulmonary arterial filling defects. Left pulmonary artery is enlarged up to 2.7 cm in axial dimension, unchanged from prior.

[page 26 of 35]
Mediastinum and hila: The large airways are normal. There are scattered prominent, nonenlarged lymph nodes seen throughout the mediastinum and hila. For example, an 8 mm precarinal lymph node (series 2 slice 41). There is no significant mediastinal or hilar lymphadenopathy.

Heart and pericardium: The heart is normal in size. There is no significant atherosclerotic calcifications along the coronary arteries. No pericardial effusion.

Lungs and pleura: No significant pulmonary nodule or infiltrate is noted. No pleural effusion. Mild scattered subpleural reticular changes are seen bilaterally. For example, series 4 image 25 demonstrates bilateral upper lobe predominant subpleural reticulation or fibrosis.

ABDOMEN PELVIS:

Liver: Normal size and morphology. Hypodense lesions along the falciform ligament are slightly more hyperdense than would be expected for focal fatty infiltration. The larger measures 14 x 11 mm (series 3 image 40), the adjacent, smaller lesion measures 11 x 10 mm (series 2 slice 42). There is a 5 mm hypodense lesion in the inferior liver tip (series 2 slice 47). Portal and hepatic venous systems are patent.

Bile ducts: Common bile duct stent is present. There is circumferential enhancement and thickening of the common bile duct. Mild intrahepatic biliary ductal dilatation with left lobe predominant pneumobilia, similar to prior.

Gallbladder: Gallbladder wall is mildly thickened and there is trace pericholecystic fluid. No additional stones or sludge. The gallbladder is not distended.

Pancreas: Dilatation of main pancreatic duct with associated atrophy of the pancreatic body and tail. Hypodense lesion in the head of the pancreas measures approximately 30 x 35 mm (series 2 slice 126). Mild fat stranding around the pancreas.

Vasculature: The celiac axis and SMA takeoffs from the abdominal aorta are high, just beneath the diaphragmatic hiatus. Hepatic arterial supply is conventional from the celiac axis. The mass does not abut or surround any of the arterial supply to the liver. There is a distinct fat plane between the portal confluence the mass. The mass does not encase the portal vein. Portal venous anatomy is somewhat unconventional in that the posterior right portal vein is supplied directly from the main portal vein, the undivided then bifurcates into anterior right portal and left portal veins.

Spleen: Normal.

Adrenals: Normal.

Kidneys/Ureters/Urinary Bladder: Kidneys enhance symmetrically. Circumscribed hypodense lesion in the superior left kidney parenchyma measures slightly complex internal density measuring 19 x 15 mm in coronal dimension. There may represent proteinaceous or hemorrhagic material within a simple cyst. Other renal hypodensities are too small to characterize, statistically likely benign cysts. No hydronephrosis or nephrolithiasis. Urinary bladder is distended with air appears grossly normal.

Reproductive organs: Status post hysterectomy. No adnexal masses. Vaginal pessary is present.

GI tract/Mesentery: Normal esophagus, stomach, and small bowel. Normal colon with decompressed transverse colon. No focal lesions or wall thickening are seen. No mesenteric adenopathy.

No ascites. No pneumoperitoneum.

Retroperitoneum: There is no significant retroperitoneal lymphadenopathy. No calcific atherosclerosis of the abdominal aorta and its branches. Normal-appearing inferior vena cava.

Bones/Soft tissues: Mild S-shaped scoliosis of the spine with associated mild to moderate degenerative changes of the lower lumbar spine centered at L4-L5. Schmorl's node in superior endplate of L1. Nonenhancing hypodense mass in the neural foramina of the right S2 and S3 (series 9 image 60) measures

[page 27 of 35]
approximately 33 x 16 mm. This is unchanged since earliest exam from outside source [REDACTED] and likely represents a perineural cyst. Soft tissues are unremarkable.

+184

IMPRESSION:

1. No significant change in the pancreatic head hypodense mass which contains fiducials and measures approximately 30 x 35 mm. There is no involvement of the hepatic arterial or portal venous systems. No lymphadenopathy.
2. Hypodense liver lesions along the falciform ligament are unchanged, documented metastases per prior biopsy. No new liver lesions.
3. Common bile duct stone with left lobe predominant pneumobilia and mild intrahepatic biliary ductal dilatation.
4. Prominent but not frankly enlarged lymph nodes in the mediastinum are indeterminate. Attention on followup. No suspicious lung nodules.

[REDACTED]

Reading Physician: [REDACTED]

Reviewed and Interpreted By: [REDACTED]

+344

[page 28 of 35]
RADIOLOGY REPORT**Patient Information**Age/Sex: [REDACTED]
Birth Date: [REDACTED]

Visit #: [REDACTED]

HAR: [REDACTED]

Signs & Symptoms: Prior whipple, liver biopsy and chole with fever; has 2 JPs
History: None Specified**Order Information**Exam(s): **CT ABD/PELVIS W CONTRAST** [REDACTED]
Exam Date: [REDACTED] +861
Ord Provider: [REDACTED]

Accession #: [REDACTED]

Final**EXAMINATION: CT OF THE ABDOMEN AND PELVIS WITH IV CONTRAST**

DATE: [REDACTED] +861

INDICATION: Pancreatic cancer with prior Whipple procedure presenting with fever. He eval for abscess.

COMPARISON: [REDACTED] +813

TECHNIQUE: Transaxial images of the abdomen and pelvis were obtained from the diaphragmatic dome to the ischial tuberosity according to routine abdomen and pelvis protocol, following the uneventful administration of intravenous contrast material, Isovue 370, 47 ml.**FINDINGS:****Liver:** The previously described hypodensity in segment IVB that was biopsy negative is no longer conspicuous. No additional focal intrahepatic lesion is identified.**Bile ducts:** Pneumobilia is decreased. Postsurgical changes of choledochojejunostomy.**Gallbladder:** Surgically absent.**Pancreas:** New postsurgical changes of Whipple procedure. The residual pancreas is atrophied with persistent dilation of the main pancreatic duct. The main portal, superior mesenteric and splenic veins are patent. No evidence of narrowing of the colic axis. Peripancreatic inflammatory changes extending inferiorly into the mesenteric root may be postoperative in nature.

[page 29 of 35]
Spleen: Normal.

Adrenals: Normal.

Kidneys/Ureters/Urinary Bladder: Simple appearing cyst in the left kidney measures 1.7 cm. Additional subcentimeter hypodensities in the right kidney are too small to characterize. No hydronephrosis. The bladder is unremarkable.

Reproductive organs: Pessary device is present within the vaginal canal. The uterus is surgically absent. No adnexal mass.

GI tract/Mesentery: The distal esophagus and stomach are unremarkable. The bowel is nondilated. The diffuse stranding is present throughout the mesentery, which is more focal surrounding the mesenteric root. Bowel wall thickening vs. underdistention/peristalsis in a short segment of mid to distal transverse colon.

No evidence of a discrete fluid collection or abscess. Percutaneous drains terminate in the left midabdomen and left upper quadrant. No pneumoperitoneum. No free fluid.

Retroperitoneum: Moderate atherosclerotic calcification of the abdominal aorta. No retroperitoneal lymphadenopathy.

Lower thorax: Normal cardiac size without pericardial or pleural effusion. Mild dependent basilar atelectasis with groundglass opacity in the peripheral left lung base. Bilateral breast implants are noted.

Soft tissues and bones: Mild body wall edema. No suspicious bony lesion or acute fracture. Central compression deformity of the superior L1 vertebral body with approximately 50% height loss is unchanged. Mild compression deformity of the L2 vertebral body is also unchanged. Stable scattered degenerative changes of the thoracolumbar spine. Midline skin staples are noted. Mild soft tissue swelling is present at the entrance site of the percutaneous drains.

Bilateral breast prostheses.

IMPRESSION:

1. Interval post surgical changes of Whipple procedure without evidence of metastasis. The previously described IVB hepatic lesion is no longer conspicuous than previously biopsy negative for malignancy.
2. Peripancreatic stranding extending along the mesenteric root is likely postoperative. There is also mild diffuse mesenteric stranding and may represent edema. No discrete intraperitoneal fluid collection.
3. Groundglass opacity in the peripheral left lung base may represent infection.

Addendum by [REDACTED] on [REDACTED] I have reviewed the resident report and agree with the impression. [REDACTED] +861

Reading Physician [REDACTED]

Reviewed and Interpreted By: [REDACTED]

[page 30 of 35]
RADIOLOGY REPORT

Patient Information

Age/Sex: [REDACTED] Female

Birth Date: [REDACTED]

Signs & Symptoms: Panc Protocol for pancreatic cancer

History: Pancreatic cancer metastasized to liver (HC code)

Order Information

Exam(s): **CT CHEST/PELV W, ABD W/WO CONTRAST**

Exam Date: [REDACTED] +813

Ord Provider: [REDACTED]

Final

EXAMINATION: CT OF THE ABDOMEN WITHOUT AND WITH IV CONTRAST AND THE CHEST AND PELVIS WITH IV CONTRAST

DATE: [REDACTED] +813

INDICATION: Evaluation for potential surgery. Panc Protocol for pancreatic cancer.

TECHNIQUE: Transaxial images of the abdomen were obtained according to pancreas mass protocol, prior to and following the uneventful administration of intravenous contrast material, Isovue 370, 58 ml. CT images of the chest and pelvis were also obtained postcontrast phase only.

COMPARISON: Multiple prior studies, most recent dated [REDACTED]. +406

FINDINGS:

CHEST:

Thyroid: No thyroid lesions.

Mediastinum and hila: A left chest port is present with the tip terminating at the cavoatrial junction. The great vessels and airways are normal. Mildly prominent pretracheal lymph nodes are stable. There is no significant mediastinal or hilar lymphadenopathy.

Heart and pericardium: The heart is normal in size. There is no significant atherosclerotic calcifications along the coronary arteries. No pericardial effusion.

[page 31 of 35]
Chest wall and breasts : Bilateral breast implants containing silicone and saline are present. The internal silicone components may be ruptured bilaterally; however, there is no rupture of the outer implant membranes are intact. There is no significant supraclavicular or axillary lymphadenopathy.

Lungs and pleura: Left greater than right basilar scarring is increased when compared to [REDACTED]. No suspicious pulmonary nodule. No pleural effusion. +353

ABDOMEN AND PELVIS:

Pancreas: Fiducial markers are redemonstrated in the pancreatic head surrounding a hypodense mass. This mass measures approximately 1.6 x 1.3 cm (series 12, image 117), though indistinction with the surrounding tissues renders measurement difficult. Overall this continues to decrease and previously measured 22 x 20 mm on [REDACTED]. Atrophy throughout the pancreatic tail is again demonstrated and there is no dilatation of the pancreatic duct. +406

Less than 180 degree abutment of main portal vein suspected along right posterolateral margin (12/109), and this could represent edema as it is quite distant from the main mass. Stable ill-defined soft tissue abuts origin of GDA (8/37), which may reflect intimal thickening from atherosclerosis as it is similarly distant from the main mass. No clear proper hepatic artery involvement. SMA is uninvolved as is proximal celiac artery.

No peripancreatic adenopathy.

Liver: Hepatic hypodensity in segment IVb adjacent to the falciform ligament measures 1.5 x 1.0 cm (12/109), previously 1.5 x 1.3 cm. Multiple additional subcentimeter hypodense lesions throughout the liver on the most recent study are unchanged or not appreciated on the current exam. Hepatic and portal veins are patent. Pneumobilia is again seen.

Bile ducts: A common bile duct stent is no longer present.

Gallbladder: No gallstones or wall thickening.

Spleen: No splenomegaly. Small granuloma

Adrenals: Mild nodularity.

Kidneys/Ureters/Urinary Bladder: Hypodense lesion within the superior pole left kidney appears mildly complex and may represent a hemorrhagic or proteinaceous cyst. This measures 1.7 x 1.2 cm, previously measured 1.9 x 1.5 cm. The right kidney is normal. No hydronephrosis. The urinary bladder is well distended and thin walled.

Reproductive organs: Uterus is surgically absent. No adnexal mass. A pessary is again seen.

GI tract/Mesentery: Normal appearance of the stomach, small bowel, and colon. No ascites or pneumoperitoneum. No obstruction.

Vascular: Mild aortobiliac atherosclerosis. The IVC is normal.

No significant lymphadenopathy in the abdomen and pelvis outside of the peripancreatic region.

No aggressive osseous lesion.

IMPRESSION:

1. Decreased size of pancreatic head mass. Less than 180 degree abutment of main portal vein. No clear arterial involvement. No hepatic lesions or adenopathy suggestive of metastatic disease at this time.

2. Slight decrease in size of complex left-sided superior pole renal cyst, probably hemorrhagic or proteinaceous cyst.

If you have any questions regarding this or any other [REDACTED] report please call [REDACTED]

[page 32 of 35]
The [REDACTED] reading area location is [REDACTED]. We are staffed 7 AM - 5 PM Monday through Friday. After hours or on weekends please call [REDACTED]

[REDACTED]

Reading Physician: [REDACTED]

[REDACTED] By: [REDACTED]

+813

[page 33 of 35]
RADIOLOGY REPORT**Patient Information**

Age/Sex [REDACTED] Female
Birth Date [REDACTED]

Visit #: [REDACTED]

HAR [REDACTED]

Signs & Symptoms
History: Pancreatic cancer metastasized to liver (HC code)

Order Information

Exam(s) CT CHEST/ABD/PELV W CONTRAST [REDACTED]

Accession # [REDACTED]

Exam Date [REDACTED] +1351

Ord Provide [REDACTED]

Final**EXAMINATION: CT OF THE CHEST, ABDOMEN, AND PELVIS WITH IV CONTRAST****DATE** [REDACTED] +1351**INDICATION:** on surveillance post whipple for pancreatic cancer.

TECHNIQUE: Transaxial images of the chest, abdomen, and pelvis were obtained from the apex of the lungs to the ischial tuberosity according to according to chest, dual phase abdomen, and pelvis protocol, following the uneventful administration of intravenous contrast material, Isovue 370, 54 ml.

COMPARISON [REDACTED] +1195**FINDINGS:****CHEST:**

Thyroid: No focal lesion in the visualized portions of the thyroid gland.

Chest wall: Left chest port with central venous catheter tip in the distal SVC. Bilateral likely ruptured breast implants again noted. There is no significant supraclavicular or axillary lymphadenopathy.

Thoracic aorta and pulmonary arteries: Normal caliber thoracic aorta. Mild to moderate atherosclerotic calcification of the descending thoracic aorta. Enlargement of the main pulmonary artery up to 3.2 cm diameter.

[page 34 of 35]
Mediastinum and hila: The large airways are normal. Grossly stable lymph node in the precarinal mediastinum measuring 10 mm short axis (7/43).

Heart and pericardium: The heart is normal in size. No visible coronary artery calcification. No pericardial effusion.

Lungs and pleura: No significant pulmonary nodule or infiltrate is noted. Unchanged areas of scarring and atelectasis throughout both lungs. No pleural effusion.

ABDOMEN PELVIS:

Liver: Normal size and parenchymal attenuation. No focal lesion. Patent hepatic vasculature.

Portal veins: Patent.

Hepatic veins: Patent.

Bile ducts: Intrahepatic pneumobilia is unchanged. Postsurgical changes of choledochojejunostomy.

Gallbladder: Surgically absent.

Pancreas: The patient has undergone pancreaticoduodenectomy. Residual pancreas is atrophic. Mild prominence of the main pancreas duct is unchanged.

Spleen: Normal.

Adrenals: Normal.

Kidneys/Ureters/Urinary Bladder: Unchanged simple left renal cyst. Probable parapelvic cysts of the right kidney and right medial posterior interpolar cyst. No hydronephrosis. Normal urinary bladder.

Reproductive organs: Pessary is noted. Uterus is surgically absent. Normal adnexa.

GI tract/Mesentery: Surgical changes related to Whipple procedure. No anastomotic narrowing. No bowel obstruction.

No ascites. No pneumoperitoneum.

Retroperitoneum: There is no significant retroperitoneal lymphadenopathy. Mild to moderate noncircumferential aortiliac atherosclerotic calcification without aneurysm.

Bones/Soft tissues: Stable degenerative change with focal height loss and kyphosis at L1. Multiple healed bilateral rib fractures. Expansile appearance of the right sacral foramina is unchanged. No acute or suspicious osseous lesion. Midline abdominal scar.

IMPRESSION:

No evidence of local recurrence or distant metastasis.

If you are a patient and have a question about your radiology report, please discuss it with your primary care provider.

If you are a health care provider and have any questions regarding this or any other report please call [REDACTED]. The [REDACTED] reading area location is [REDACTED]. We are staffed 7 AM - 5 PM Monday through Friday. After hours or on weekends please call [REDACTED].

Report E-Signed By [REDACTED]

+1351

[page 35 of 35]
Reading Physician: [REDACTED]

Reviewed and Interpreted By: [REDACTED]

+1351

Source: NCI Genomic Data Commons file 17cdb7c1-6120-4d13-ba44-50cab1ab1c88 (ER0396 ER-B0GF Clinical Report_Redacted_Sanitized.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).